Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3DQ, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3DQ-01A (Primary Tumor).

	lw 10/21/11	

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

2. THYROID:

SPECIMEN TYPE: Total thyroidectomy.

TUMOR SITE: Right lobe.

HISTOLOGIC TYPE:
Papillary carcinoma, follicular variant.

TUMOR SIZE: Greatest dimension: 1.0 cm.

FOCALITY:
Multifocal (1 additional 0.3 cm focus, also in the right lobe).

LYMPH NODES:
Both (2) lymph nodes negative for tumor.

EXTENT OF INVASION
PRIMARY TUMOR:
pT1: tumor size <2 cm, limited to thyroid.

REGIONAL LYMPH NODES:
pN0: No regional lymph node metastasis.

DISTANT METASTASIS:
pMX: Cannot be assessed

MARGINS: Margins are uninvolved

VENOUS/LYMPHATIC INVASION: Absent

ADDITIONAL PATHOLOGIC FINDINGS:
Nodular hyperplasia and chronic lymphocytic thyroiditis consistent with nodular Hashimoto's thyroiditis.

NOTE: This case was reviewed at the
Dr. _____ was present and he concurs with the above diagnosis.

1C15-0-3

*carcinoma, papillary, follicular
variant 8340/3*

Site: thyroid, NOS 073 9

*lw
10/21/11*

Source: NCI Genomic Data Commons file af18a95d-38b7-4f6a-bed4-b1e44e0d5a02 (TCGA-ET-A3DQ.C6AC3695-85B8-400F-A539-54305CD46DFF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).